Somatic mutation profile of tumor specimen C3N-00312-02 (aliquot CPT0009050009) from CPTAC case C3N-00312, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.8 years (25,123 days).
Specimen C3N-00312-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d99284a-ab56-442b-95c1-49f216e16359.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00312-31 (Blood Derived Normal), aliquot CPT0009090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d00a80af-8cf9-4963-a508-6d8ca559b2a8

The open-access MAF lists 92 somatic variants for this specimen: 67 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Frame Shift Del 7, Splice Site 5, 3'UTR 4, Nonsense Mutation 3, Splice Region 3, In Frame Del 2, 5'UTR 2, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPERG | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as rs1366216301; called by muse, mutect2, varscan2
- CHD7 | c.6499G>A p.V2167I | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs971937875; called by muse, mutect2, varscan2
- FMNL3 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV53302674; called by mutect2, varscan2
- GGA3 | c.1445C>T p.S482F (on ENST00000537686 / NM_138619.4; = p.S449F on NM_014001.5) | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1178473582; called by muse, mutect2, varscan2
- HPS6 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 189/701 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs753587696; called by muse, mutect2, varscan2
- IFT81 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767705291; called by muse, mutect2, varscan2
- LPAR6 | c.756T>G p.Y252* | Nonsense Mutation (SNP) | VAF 50/140 reads (36%) | catalogued as rs944321155, CM153496; called by muse, mutect2, varscan2
- MAPT | c.1677C>G p.N559K (on ENST00000262410 / NM_001377265.1; = p.N167K on NM_005910.5) | Missense Mutation (SNP) | VAF 101/399 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52242881; called by muse, mutect2, varscan2
- NCKAP5L | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs766675424; called by muse, mutect2, varscan2
- OR2T6 | c.369C>A p.Y123* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV63215569; called by muse, mutect2, varscan2
- PCLO | c.2974A>G p.K992E | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as rs1246670068; called by muse, mutect2, varscan2
- PGAP6 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV51740282; called by muse, mutect2, varscan2
- PHTF1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 125/375 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs759006715; called by muse, mutect2, varscan2
- PPP1R12C | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52383486; called by muse, mutect2, varscan2
- RYR1 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 145/558 reads (26%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); catalogued as COSV62108397; called by muse, mutect2, varscan2
- SH3PXD2A | c.1555C>T p.R519W (on ENST00000369774 / NM_001365079.1; = p.R491W on NM_014631.2) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100280177, COSV60118315; called by muse, mutect2, varscan2
- TCOF1 | c.2659-1G>C p.X887_splice (on ENST00000377797 / NM_001135243.1; = p.X810_splice on NM_000356.4) | Splice Site (SNP) | VAF 108/481 reads (22%) | catalogued as COSV60345624; called by muse, mutect2, varscan2
- YLPM1 | c.4604C>A p.S1535* | Nonsense Mutation (SNP) | VAF 78/240 reads (33%) | catalogued as COSV53119977; called by muse, mutect2, varscan2
- ZNF655 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774474239, COSV53159970; called by muse, mutect2, varscan2
- ZNF790 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63213016; called by muse, mutect2, varscan2
- ADCY9 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 110/443 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ASIC2 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ATRNL1 | c.1726C>A p.H576N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- BCAN | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CENPV | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CETN2 | c.162+2C>T p.X54_splice | Splice Site (SNP) | VAF 8/12 reads (67%) | called by muse, varscan2
- CFAP74 | c.4664_4666del p.P1555del | In Frame Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAI4 | c.1291+2T>A p.X431_splice | Splice Site (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- DNAJC1 | c.635+2T>C p.X212_splice | Splice Site (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- DNM2 | c.2443C>A p.P815T (on ENST00000355667 / NM_001005360.3; = p.P811T on NM_004945.3) | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EYA3 | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAL | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GCN1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRN | c.934-2A>G p.X312_splice | Splice Site (SNP) | VAF 119/446 reads (27%) | called by muse, mutect2, varscan2
- HMCN1 | c.9224C>A p.T3075N | Missense Mutation (SNP) | VAF 125/462 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- HSPA8 | c.1677A>T p.Q559H | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- IGKV1-12 | c.257del p.G86Afs*? | Frame Shift Del (DEL) | VAF 71/576 reads (12%) | called by mutect2, pindel, varscan2
- ITPRID2 | c.332del p.S111Ifs*44 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- LHX6 | c.253-4C>A | Splice Region (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- LILRB2 | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- LRP2 | c.2873T>G p.L958R | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MTRF1L | c.188A>C p.E63A | Missense Mutation (SNP) | VAF 160/604 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MYO7A | c.2272T>G p.F758V | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NBPF14 | c.7948C>G p.L2650V | Missense Mutation (SNP) | VAF 91/433 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NLGN2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 146/482 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR2C1 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OBSCN | c.9382T>C p.W3128R | Missense Mutation (SNP) | VAF 125/419 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2L3 | c.826T>G p.F276V | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- OR4Q2 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PBRM1 | c.3755del p.N1252Mfs*17 (on ENST00000296302 / NM_001366071.2; = p.N1227Mfs*17 on NM_018313.5) | Frame Shift Del (DEL) | VAF 59/188 reads (31%) | called by mutect2, pindel, varscan2
- PPP2CA | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A12 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SORBS2 | c.286G>A p.D96N (on ENST00000284776 / NM_021069.5; = p.D142N on NM_003603.6) | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT6 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SYNE2 | c.13226_13270del p.M4409_S4424delinsT | In Frame Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel
- TMEM108 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TRGV8 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTLL7 | c.1861_1862delinsA p.F621Ifs*6 | Frame Shift Del (DEL) | VAF 59/354 reads (17%) | called by pindel, varscan2*
- UBE2D3 | c.27A>G p.E9= | Splice Region (SNP) | VAF 70/256 reads (27%) | called by muse, mutect2, varscan2
- UNC13B | c.1215G>A p.G405= | Splice Region (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- USH2A | c.15174del p.L5059Cfs*3 | Frame Shift Del (DEL) | VAF 60/286 reads (21%) | called by mutect2, pindel, varscan2
- VHL | c.402dup p.L135Ifs*9 | Frame Shift Ins (INS) | VAF 104/327 reads (32%) | called by mutect2, pindel, varscan2
- WDR54 | c.1003_1004del p.*335Rfs*? | Frame Shift Del (DEL) | VAF 36/187 reads (19%) | called by pindel, varscan2
- ZNF19 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF649 | c.1119del p.F374Lfs*88 | Frame Shift Del (DEL) | VAF 33/173 reads (19%) | called by mutect2, pindel, varscan2
- ADH4 | c.537A>C p.G179= | Silent (SNP) | VAF 57/174 reads (33%) | called by muse, mutect2, varscan2
- AUTS2 | c.102G>T p.A34= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- BRD3 | c.1161C>T p.C387= | Silent (SNP) | VAF 49/203 reads (24%) | catalogued as rs1185563179, COSV100325348; called by muse, mutect2, varscan2
- CALB2 | c.516C>T p.G172= | Silent (SNP) | VAF 57/210 reads (27%) | called by muse, mutect2, varscan2
- CDK13 | c.1035A>T p.G345= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- CSMD2 | c.6570C>T p.N2190= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs377152497; called by muse, mutect2
- DDX17 | c.1581A>G p.L527= | Silent (SNP) | VAF 181/613 reads (30%) | catalogued as rs369638680; called by muse, mutect2, varscan2
- DST | c.10587A>G p.V3529= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1292771928; called by muse, mutect2, varscan2
- EXOSC9 | c.468C>G p.A156= | Silent (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- FBLN7 | c.930C>T p.Y310= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as rs148395500; called by muse, mutect2, varscan2
- ITGA7 | c.3165G>A p.L1055= (on ENST00000555728; = p.L1011= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/517 reads (25%) | catalogued as COSV57696802; called by muse, mutect2, varscan2
- PDE8B | c.792A>G p.K264= | Silent (SNP) | VAF 48/185 reads (26%) | called by muse, mutect2, varscan2
- RDH10 | c.177T>A p.R59= | Silent (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- TTN | c.24864T>C p.A8288= (on ENST00000591111; = p.A7361= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/209 reads (24%) | called by muse, mutect2, varscan2
- TUBB6 | c.270C>T p.F90= | Silent (SNP) | VAF 108/354 reads (31%) | catalogued as rs1324251587, COSV100480964; called by muse, varscan2
- ZFP36 | c.348G>T p.R116= (on ENST00000594442; = p.R110= on NM_003407.5) | Silent (SNP) | VAF 63/247 reads (26%) | called by muse, mutect2, varscan2
- BRCA1 | c.*790G>T | 3'UTR (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- BTBD10 | c.101+5043A>C | Intron (SNP) | VAF 39/108 reads (36%) | catalogued as rs1194565378; called by muse, mutect2, varscan2
- COG6 | c.-61G>A | 5'UTR (SNP) | VAF 104/409 reads (25%) | catalogued as rs770910922; called by muse, mutect2, varscan2
- MFSD4B | c.*415T>A | 3'UTR (SNP) | VAF 55/182 reads (30%) | called by muse, mutect2, varscan2
- PAK1 | c.*115T>A | 3'UTR (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- POM121L9P | n.773C>T | RNA (SNP) | VAF 97/479 reads (20%) | catalogued as rs1209058384; called by muse, mutect2, varscan2
- SEC31B | c.*11del | 3'UTR (DEL) | VAF 45/174 reads (26%) | called by mutect2, pindel, varscan2
- USP30 | c.-42C>T | 5'UTR (SNP) | VAF 8/161 reads (5%) | catalogued as rs1566082355; called by muse, mutect2
- XIAP | chrX:123860160 C>T | 5'Flank (SNP) | VAF 138/261 reads (53%) | called by muse, mutect2, varscan2
